Somatic mutation profile of tumor specimen TARGET-10-PARABU-09A (aliquot TARGET-10-PARABU-09A-01D) from TARGET case TARGET-10-PARABU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,451 days).
Specimen TARGET-10-PARABU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 932a13b3-957f-462b-af34-843a15cfb9cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARABU-10A (Blood Derived Normal), aliquot TARGET-10-PARABU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dd62e41-e0e5-4349-9d8c-c5bd505ff43a

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 3'UTR 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs28933386, CM013422, COSV61006575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GTF3C2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs763634070, COSV53128988; called by muse, mutect2, varscan2
- OR8D2 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62489224; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- ALKBH5 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- DYNC1H1 | c.8117T>G p.I2706S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAL3ST2 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CCDC125 | c.1030T>C p.L344= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- OGFR | c.567G>A p.T189= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs756791766; called by muse, mutect2, varscan2
- SRCIN1 | c.2388G>A p.K796= (on ENST00000621492; = p.K762= on NM_025248.3) | Silent (SNP) | VAF 47/110 reads (43%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-2+32G>A | Intron (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- NGF | c.*52C>T | 3'UTR (SNP) | VAF 11/27 reads (41%) | catalogued as COSV101049644; called by muse, mutect2, varscan2
- STK16 | c.-10C>T | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- XRCC3 | c.*4G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as rs760585240; called by muse, varscan2
